Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A015, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A015-01A (Primary Tumor).

Diagnosis:

Rectosigmoid with a colon and rectal carcinoma of the histological type of a moderately differentiated colorectal adenocarcinoma, extending a max of 1.5 cm to the aboral resection margin, and measuring a maximum of 2.5 cm in diameter at the widest point, located at the base of a tubulovillous adenoma with severe epithelial dysplasia (synonymous: profound intraepithelial neoplasia). Invasive spread of tumor to the submucosal layer.

Oral and aboral resection margin is tumor-free.

Eighteen mesocolic and periproctal lymph nodes are tumor-free and display uncharacteristically reactive changes.

Stage of tumor: PT1 pN0 (0/18) L0, V0, G2 R0.

1CD-0-3

adenocarcinoma, NOS 8140/3

Site: Rectum C20.9 per 3/31/11

Source: NCI Genomic Data Commons file 00cba334-64c7-4664-a970-71210ead762a (TCGA-AG-A015.FDBE42F3-4A2C-4218-A741-04F23A6689C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).